Somatic mutation profile of tumor specimen 0DKMG7 from CCDI case PBBYHV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Germinoma; Tissue or organ of origin: Brain stem; Age at diagnosis: 17.5 years (6,394 days).
Specimen 0DKMG7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a04346a-6dca-454b-9dfa-a87802f77439.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKMFZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f03ecd1-4f92-49a9-9d86-c309f950bc81

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 114/1128 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, varscan2
- AHNAK2 | c.6572C>T p.S2191F | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60931641; called by muse, varscan2
- B3GLCT | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 92/712 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758647803, COSV58453711; called by muse, varscan2
- CDK5RAP2 | c.1691A>G p.Y564C | Missense Mutation (SNP) | VAF 181/994 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752307809; called by muse, varscan2
- DNAI3 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 104/800 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.04); catalogued as rs1391802558; called by muse, varscan2
- DMGDH | c.2293G>C p.A765P | Missense Mutation (SNP) | VAF 125/1230 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.035); called by muse, varscan2
- HNRNPA0 | c.845G>A p.G282D | Missense Mutation (SNP) | VAF 66/545 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, varscan2
- PGAP1 | c.1350G>A p.K450= | Splice Region (SNP) | VAF 221/1004 reads (22%) | called by muse, varscan2
- CEP192 | c.7359G>C p.V2453= | Silent (SNP) | VAF 149/567 reads (26%) | called by muse, varscan2
